Somatic mutation profile of tumor specimen TARGET-10-PATITY-09A (aliquot TARGET-10-PATITY-09A-01D) from TARGET case TARGET-10-PATITY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,125 days).
Specimen TARGET-10-PATITY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12685107-1bea-4cd0-a29b-7f5aaa513ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATITY-10A (Blood Derived Normal), aliquot TARGET-10-PATITY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31c8eb73-ad56-4e1e-8966-edc594a42c87

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Silent 2, Frame Shift Del 2, Splice Region 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0A1 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52873995; called by muse, mutect2, varscan2
- BCAS1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539868796, COSV65086779; called by muse, mutect2, varscan2
- BCL6 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042221684, COSV51652672; called by muse, mutect2
- COL6A2 | c.1269G>A p.P423= | Splice Region (SNP) | VAF 7/12 reads (58%) | catalogued as rs144136807; ClinVar: uncertain significance; called by muse, varscan2
- CRACD | c.1420del p.A474Pfs*19 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs1183825963; called by mutect2, pindel, varscan2
- HSDL2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52715346; called by muse, mutect2, varscan2
- MAPK4 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs750579920, COSV68542441; called by muse, mutect2
- NOTCH1 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335854366, COSV53057576; called by muse, mutect2, varscan2
- PER3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs529267363, COSV62706212; called by muse, mutect2, varscan2
- TP53INP1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753451554, COSV61331682; called by muse, mutect2, varscan2
- TRHDE | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs200482271, COSV53857265; called by muse, mutect2, varscan2
- ABCC6 | c.2717_2720del p.T906Rfs*24 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | called by pindel, varscan2
- PPP1R13L | c.58C>T p.L20= | Splice Region (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- KCNH4 | c.369C>T p.V123= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs1392042959; called by muse, mutect2, varscan2
- UBXN10 | c.165C>T p.G55= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs557209705, COSV66772536; called by muse, mutect2, varscan2
- CCDC150 | c.*26T>C | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs762173025; called by muse, mutect2, varscan2
- EIF3L | c.34-68G>A | Intron (SNP) | VAF 19/32 reads (59%) | catalogued as COSV66045848; called by muse, mutect2, varscan2
- EMC1 | c.220+62A>G | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- TUBB3 | chr16:89938611 C>T | 3'Flank (SNP) | VAF 19/62 reads (31%) | catalogued as rs531173631; called by muse, mutect2, varscan2
